CCDI case PBBYVA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/47717da1-7bea-43aa-965f-b25b22f02c62

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.6 years (4,229 days).

Biospecimens (3 samples)
- Sample 0DL0IV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL0J4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL0JX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
